Somatic mutation profile of tumor specimen TCGA-CC-A9FS-01A (aliquot TCGA-CC-A9FS-01A-11D-A36X-10) from TCGA case TCGA-CC-A9FS, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 55.2 years (20,157 days).
Specimen TCGA-CC-A9FS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7773dce2-e859-4145-8c14-cbcaeea43540.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A9FS-10A (Blood Derived Normal), aliquot TCGA-CC-A9FS-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec2970b0-4f76-4353-9ddd-979aabcc1f6b

The open-access MAF lists 117 somatic variants for this specimen: 88 protein-altering or splice-affecting, 26 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 26, Nonsense Mutation 7, Frame Shift Del 2, Intron 1, Frame Shift Ins 1, In Frame Del 1, 3'UTR 1, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.4437A>T p.E1479D | Missense Mutation (SNP) | VAF 97/232 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.51); catalogued as COSV101330155; called by muse, mutect2, varscan2
- ACAT1 | c.1268T>G p.L423R | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99759374; called by muse, mutect2, varscan2
- ADAT1 | c.28C>A p.L10I | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100329287; called by muse, mutect2, varscan2
- AL645922.1 | c.2075A>C p.H692P | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.505); catalogued as COSV100191414; called by muse, mutect2, varscan2
- APPBP2 | c.1112A>G p.D371G | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.857); catalogued as COSV99319837; called by muse, mutect2, varscan2
- ARID1A | c.3385A>T p.K1129* | Nonsense Mutation (SNP) | VAF 25/74 reads (34%) | catalogued as COSV100252998, COSV61384817; called by muse, mutect2, varscan2
- ASCC2 | c.963G>T p.E321D | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as COSV100316450; called by muse, mutect2, varscan2
- ATR | c.1415C>G p.S472C | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.293); catalogued as rs752635785, COSV100638509, COSV63388476; called by muse, mutect2, varscan2
- AXIN1 | c.1904G>A p.W635* | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as COSV51995733; called by muse, mutect2, varscan2
- BOD1L1 | c.3034C>T p.L1012F | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV99240145; called by muse, mutect2
- CADPS2 | c.2932C>A p.P978T | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.123); catalogued as COSV100465269, COSV100466766; called by muse, mutect2
- CCDC172 | c.203T>G p.L68R | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV60936721; called by muse, mutect2, varscan2
- CCT6B | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.072); catalogued as rs983913925, COSV100030936; called by muse, mutect2, varscan2
- CDKN1B | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 349/915 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV57430252, COSV99964040; called by muse, mutect2, varscan2
- CLCA4 | c.2474G>A p.S825N | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100991180; called by muse, mutect2, varscan2
- CLEC3B | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56109490; called by muse, mutect2, varscan2
- COL22A1 | c.4580G>T p.G1527V | Missense Mutation (SNP) | VAF 56/489 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs951294502, COSV100280268; called by muse, mutect2, varscan2
- COL5A3 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99319577; called by muse, mutect2, varscan2
- CUBN | c.9860C>T p.T3287I | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV100913377; called by muse, varscan2
- DCAF6 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 91/138 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV56587638; called by muse, mutect2, varscan2
- DDX17 | c.1319G>T p.R440I | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV99318947; called by muse, mutect2, varscan2
- DHX37 | c.3279G>T p.K1093N | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100439441; called by muse, mutect2, varscan2
- DNM1 | c.1394G>T p.R465L | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100360268, COSV57855099; called by muse, mutect2, varscan2
- DOK6 | c.467C>T p.T156I | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.155); catalogued as COSV66937142; called by muse, mutect2, varscan2
- DPP9 | c.1215G>T p.R405S (on ENST00000598800; = p.R434S on NM_139159.5) | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99506420; called by muse, mutect2, varscan2
- EIF4A3 | c.1034A>T p.Q345L | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.716); catalogued as COSV99484185; called by muse, mutect2, varscan2
- ENGASE | c.1424T>C p.V475A | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1401925426, COSV100285925; called by muse, mutect2, varscan2
- EPHA3 | c.64C>A p.L22M | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.135); catalogued as COSV100347918; called by muse, mutect2, varscan2
- ERN2 | c.1022G>C p.S341T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV56834946, COSV99892183; called by mutect2, varscan2
- FAT3 | c.12844G>A p.V4282M | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99968250; called by muse, mutect2, varscan2
- FCAR | c.658C>G p.H220D | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100629168, COSV62030803; called by muse, mutect2, varscan2
- GSN | c.35G>T p.C12F | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); catalogued as COSV100376477; called by muse, mutect2, varscan2
- H3C10 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.285); catalogued as COSV100297666; called by muse, mutect2, varscan2
- HOXA13 | c.464C>G p.P155R | Missense Mutation (SNP) | VAF 92/207 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as COSV99763704; called by muse, mutect2, varscan2
- IGDCC3 | c.1142A>G p.N381S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.359); catalogued as COSV100031449; called by muse, mutect2, varscan2
- ILDR1 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs200029008, COSV99878826; called by muse, mutect2, varscan2
- KIAA1614 | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100851354, COSV62554039; called by muse, mutect2, varscan2
- KLF11 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV59940770; called by muse, mutect2, varscan2
- KRT13 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as rs746117318, COSV55839059; called by muse, mutect2, varscan2
- LEXM | c.872C>T p.T291I | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV100827723; called by muse, mutect2, varscan2
- LOXL3 | c.817G>T p.G273W | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1192497341, COSV51206025, COSV99239876; called by muse, mutect2, varscan2
- LRRC8E | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs200370523, COSV100143101; called by muse, mutect2, varscan2
- MMP11 | c.1022G>A p.S341N | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV99303333; called by muse, mutect2, varscan2
- MON2 | c.3166G>T p.G1056* | Nonsense Mutation (SNP) | VAF 55/168 reads (33%) | catalogued as COSV99743314; called by muse, mutect2, varscan2
- MUC17 | c.2401C>A p.P801T | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV100074732, COSV60303356; called by muse, mutect2
- NFIC | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.266); catalogued as COSV100545601; called by muse, mutect2, varscan2
- NLGN4X | c.1733T>A p.V578E | Missense Mutation (SNP) | VAF 97/163 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99323506; called by muse, mutect2, varscan2
- NMS | c.340T>C p.S114P | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV100966640; called by muse, mutect2, varscan2
- OCIAD2 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 162/392 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.125); catalogued as COSV99906660; called by muse, mutect2, varscan2
- OR10A6 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 90/248 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100564342; called by muse, mutect2, varscan2
- OR56A3 | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as rs763056940, COSV100290345; called by muse, mutect2, varscan2
- OR8H1 | c.423C>A p.C141* | Nonsense Mutation (SNP) | VAF 50/124 reads (40%) | catalogued as rs772055350, COSV57296218; called by muse, mutect2, varscan2
- OSBP | c.1623G>C p.Q541H | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99803317; called by muse, mutect2
- PCDHGA2 | c.2363A>G p.K788R | Missense Mutation (SNP) | VAF 24/277 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); catalogued as rs1336534139, COSV53919011, COSV99544960; called by muse, mutect2
- PDPR | c.1535C>G p.S512C | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as COSV99848758; called by muse, mutect2, varscan2
- PHC1 | c.899G>A p.G300D | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.34); catalogued as rs756274493, COSV101418688; called by muse, mutect2, varscan2
- PLCG1 | c.527A>T p.D176V | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99719213; called by muse, mutect2, varscan2
- PRKG1 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64816672; called by muse, mutect2, varscan2
- PRSS55 | c.1001G>A p.R334K | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1394481817, COSV100153865; called by muse, mutect2, varscan2
- PRTG | c.1834A>G p.K612E | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV101221335; called by muse, mutect2, varscan2
- RASA1 | c.299_319del p.A100_A106del | In Frame Del (DEL) | VAF 20/84 reads (24%) | catalogued as rs771844907; called by mutect2, varscan2
- RBM15B | c.1452G>T p.R484S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100082307; called by muse, mutect2, varscan2
- RC3H2 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV100106879; called by muse, mutect2, varscan2
- RSAD1 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as COSV99364383; called by muse, mutect2, varscan2
- RYK | c.1385G>T p.R462M (on ENST00000620660 / NM_001005861.2; = p.R459M on NM_002958.4) | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99938543; called by muse, mutect2, varscan2
- SCAMP4 | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 66/116 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.057); catalogued as COSV100290824; called by muse, mutect2, varscan2
- SCN9A | c.473C>A p.T158N | Missense Mutation (SNP) | VAF 76/257 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1166699182, COSV100313872; called by muse, mutect2, varscan2
- SLC12A6 | c.3181A>C p.K1061Q (on ENST00000354181 / NM_001365088.1; = p.K1010Q on NM_005135.2) | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs751234919, COSV99273194; called by muse, mutect2, varscan2
- SPR | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 18/434 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV99318093; called by muse, mutect2
- ST8SIA6 | c.344G>A p.W115* | Nonsense Mutation (SNP) | VAF 133/361 reads (37%) | catalogued as COSV101112203, COSV66472229; called by muse, mutect2, varscan2
- STARD10 | c.275G>T p.R92L | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100600438, COSV100600489; called by muse, mutect2, varscan2
- SYTL2 | c.2519A>G p.N840S (on ENST00000528231 / NM_001162951.2; = p.N816S on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/217 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.741); catalogued as rs1201074769, COSV100313783; called by muse, mutect2, varscan2
- TATDN2 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 85/201 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV99813701; called by muse, mutect2, varscan2
- THOC2 | c.2706A>C p.E902D | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99834009; called by muse, mutect2, varscan2
- TNPO2 | c.899C>G p.P300R | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100790405; called by muse, mutect2, varscan2
- TPO | c.975C>A p.D325E | Missense Mutation (SNP) | VAF 371/999 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100221843, COSV61099765; called by muse, mutect2, varscan2
- TRIM65 | c.851G>A p.C284Y | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs867386555, COSV53934804; called by muse, mutect2, varscan2
- TSC2 | c.911G>A p.W304* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | catalogued as rs45517140, CM090987, COSV99555092; ClinVar: not provided; called by muse, mutect2, varscan2
- TTN | c.13804G>A p.V4602I (on ENST00000591111; = p.V3675I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/83 reads (43%) | PolyPhen benign (0.006); catalogued as COSV100625995; called by muse, mutect2, varscan2
- XIRP2 | c.313C>A p.R105S | Missense Mutation (SNP) | VAF 78/196 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as rs780403837, COSV54695932, COSV99746418; called by muse, mutect2, varscan2
- XKR4 | c.1456G>T p.A486S | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.933); catalogued as COSV59324679, COSV59342013; called by muse, mutect2, varscan2
- XRN2 | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101017928; called by muse, mutect2, varscan2
- YY1AP1 | c.1203G>T p.M401I (on ENST00000295566 / NM_139118.2; = p.M344I on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/89 reads (75%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV99804557; called by muse, varscan2
- ZNF157 | c.680T>A p.F227Y | Missense Mutation (SNP) | VAF 123/158 reads (78%) | SIFT tolerated (0.09); PolyPhen benign (0.444); catalogued as COSV100998523; called by muse, mutect2, varscan2
- AXIN1 | c.520_538del p.K174Pfs*62 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, pindel
- AXIN2 | c.775del p.A259Rfs*3 | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | called by mutect2, pindel, varscan2
- FN1 | c.4551dup p.V1518Cfs*20 | Frame Shift Ins (INS) | VAF 33/120 reads (28%) | called by mutect2, pindel, varscan2
- OR2T8 | c.595A>G p.I199V | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.107); called by muse, mutect2
- ADGRB1 | c.1974T>A p.P658= | Silent (SNP) | VAF 30/158 reads (19%) | catalogued as COSV100030201; called by muse, mutect2, varscan2
- ARHGEF26 | c.2079C>T p.T693= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV100726667; called by muse, mutect2, varscan2
- ARSA | c.54C>T p.A18= | Silent (SNP) | VAF 197/496 reads (40%) | catalogued as COSV99332474; called by muse, mutect2, varscan2
- CACNA1S | c.5025T>C p.H1675= | Silent (SNP) | VAF 59/83 reads (71%) | catalogued as rs751492580, COSV100755284; called by muse, mutect2, varscan2
- CEP126 | c.1701T>C p.H567= | Silent (SNP) | VAF 24/272 reads (9%) | catalogued as COSV99681360; called by muse, mutect2
- CLIC6 | c.1071C>T p.D357= | Silent (SNP) | VAF 12/156 reads (8%) | catalogued as rs952251348, COSV100659300; called by muse, mutect2
- CPSF6 | c.1023G>T p.P341= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as COSV99879635; called by muse, mutect2, varscan2
- CSPG4 | c.2148G>T p.G716= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV100414088; called by muse, mutect2, varscan2
- DISC1 | c.1548G>A p.L516= | Silent (SNP) | VAF 20/260 reads (8%) | catalogued as rs769340270, COSV99698414; called by muse, mutect2
- EPHX3 | c.21C>A p.T7= | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as COSV99651263; called by muse, mutect2, varscan2
- FAM50B | c.849G>A p.E283= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV100976599; called by muse, mutect2, varscan2
- FANCC | c.1362G>A p.L454= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV100002939; called by muse, mutect2, varscan2
- FAT2 | c.12447G>A p.P4149= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as rs758682292, COSV99943238; called by muse, mutect2, varscan2
- FUT7 | c.880C>A p.R294= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV99688287; called by muse, mutect2, varscan2
- GPR1 | c.912T>C p.Y304= | Silent (SNP) | VAF 47/124 reads (38%) | catalogued as rs761263716, COSV101329861; called by muse, mutect2, varscan2
- GYPE | c.114T>C p.S38= | Silent (SNP) | VAF 32/336 reads (10%) | catalogued as COSV100679426; called by muse, mutect2
- KLHDC3 | c.1146G>T p.G382= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV99763892; called by muse, mutect2, varscan2
- MACC1 | c.1773G>A p.Q591= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV100256179; called by muse, mutect2, varscan2
- OPA1 | c.2856A>G p.Q952= (on ENST00000361510 / NM_130837.3; = p.Q897= on NM_015560.3) | Silent (SNP) | VAF 43/109 reads (39%) | catalogued as COSV100655437; called by muse, mutect2, varscan2
- OR52B4 | c.381C>A p.A127= | Silent (SNP) | VAF 55/150 reads (37%) | catalogued as COSV101281601; called by muse, mutect2, varscan2
- OR8G2P | c.627G>A p.T209= | Silent (SNP) | VAF 43/109 reads (39%) | catalogued as rs749501678; called by muse, mutect2, varscan2
- PEAK3 | c.579G>A p.A193= | Silent (SNP) | VAF 54/200 reads (27%) | catalogued as rs200575519, COSV100574314, COSV100574366; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.396G>A p.E132= | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as rs1429255237, COSV99461699; called by muse, mutect2, varscan2
- SYNPO2 | c.2226T>A p.A742= | Silent (SNP) | VAF 45/88 reads (51%) | catalogued as COSV100206267; called by muse, mutect2, varscan2
- TAS2R38 | c.402C>T p.S134= | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as COSV101516518; called by muse, mutect2, varscan2
- THOC5 | c.1632G>C p.L544= | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as COSV100803644; called by muse, mutect2, varscan2
- CR1 | c.487+12038T>G | Intron (SNP) | VAF 46/479 reads (10%) | catalogued as COSV100887977; called by muse, mutect2
- MIR1265 | n.33G>C | RNA (SNP) | VAF 22/73 reads (30%) | catalogued as COSV101367316; called by muse, mutect2, varscan2
- VGF | c.*2T>A | 3'UTR (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99973157; called by muse, mutect2
